Gene-level copy-number profile of tumor specimen TCGA-22-4594-01A from TCGA case TCGA-22-4594, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.5 years (22,115 days).
Specimen TCGA-22-4594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f49e7012-8ca3-4082-924c-443d842465d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4594-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/65889eb2-5775-4feb-85e9-9dc64c085c6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,259; copy number 2: 28,394; copy number 3: 16,847; copy number 4: 4,181; copy number 5: 69; copy number 7: 8; copy number 25: 24; copy number 27: 19; copy number 29: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4594-01A-01D-1195-01): tumor purity 0.24, ploidy 4.98, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 138 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,789,805–62,286,225, 8 genes, copy number 5 (within-gene range 3–5): AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr13:113,105,788–113,208,715, 8 genes, copy number 7: F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2.
- chr18:44,522,366–45,844,094, 19 genes, copy number 27 (within-gene range 4–27): MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15.
- chr18:45,983,536–46,072,272, 1 gene, copy number 25 (within-gene range 4–25): PSTPIP2.
- chr18:46,028,306–47,102,243, 23 genes, copy number 25 (within-gene range 4–25): AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2.
- chr18:48,026,672–49,013,819, 18 genes, copy number 29: ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3.
- chr20:17,693,672–20,360,703, 61 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
